Somatic mutation profile of tumor specimen TCGA-CN-A642-01A (aliquot TCGA-CN-A642-01A-12D-A30E-08) from TCGA case TCGA-CN-A642, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Tongue, NOS; AJCC pathologic stage: Stage IVB; Tumor grade: G3; Age at diagnosis: 57.5 years (21,011 days).
Specimen TCGA-CN-A642-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0b26d804-eb75-474c-b6b3-f5df7add46b0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CN-A642-10A (Blood Derived Normal), aliquot TCGA-CN-A642-10A-01D-A30H-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/087ab0f9-202c-477e-ba9d-4b07c28cb6c5

The open-access MAF lists 84 somatic variants for this specimen: 67 protein-altering or splice-affecting, 15 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 52, Silent 15, Nonsense Mutation 7, Splice Region 3, Frame Shift Del 2, Splice Site 2, Frame Shift Ins 1, RNA 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- HRAS | c.37G>T p.G13C | Missense Mutation (SNP) | VAF 36/51 reads (71%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen benign (0.385); catalogued as rs104894228, CM060018, COSV54236651, COSV54236730, COSV54241641; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ANO4 | c.555C>T p.F185= (on ENST00000392977 / NM_001286615.2; = p.F150= on NM_178826.4) | Splice Region (SNP) | VAF 21/66 reads (32%) | catalogued as COSV100151329; called by muse, mutect2, varscan2
- BARD1 | c.701A>T p.E234V | Missense Mutation (SNP) | VAF 27/79 reads (34%) | SIFT tolerated (0.09); PolyPhen benign (0.152); catalogued as COSV99637616; called by muse, mutect2, varscan2
- BRD1 | c.89C>T p.T30M | Missense Mutation (SNP) | VAF 121/162 reads (75%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.875); catalogued as rs1331474742, COSV99349055; called by muse, mutect2, varscan2
- CAPN15 | c.1511C>T p.A504V | Missense Mutation (SNP) | VAF 60/210 reads (29%) | SIFT tolerated (0.5); PolyPhen benign (0.005); catalogued as rs553495909, COSV99562076; called by muse, mutect2, varscan2
- CASP8 | c.202C>T p.R68* | Nonsense Mutation (SNP) | VAF 20/51 reads (39%) | catalogued as rs777784105, COSV51846869; called by muse, mutect2, varscan2
- CCDC18 | c.1681G>C p.E561Q (on ENST00000343253 / NM_001306076.1; = p.E562Q on NM_206886.4) | Missense Mutation (SNP) | VAF 9/15 reads (60%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.919); catalogued as COSV100159107; called by muse, mutect2
- CDK14 | c.541G>A p.E181K (on ENST00000380050 / NM_001287135.2; = p.E163K on NM_012395.3) | Missense Mutation (SNP) | VAF 20/55 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV99723256; called by muse, mutect2, varscan2
- CHD8 | c.2764G>A p.A922T (on ENST00000646647 / NM_001170629.2; = p.A643T on NM_020920.4) | Missense Mutation (SNP) | VAF 5/9 reads (56%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); catalogued as rs1013103711, COSV101303007; ClinVar: uncertain significance; called by muse, mutect2
- COL11A2 | c.2086G>A p.E696K (on ENST00000341947 / NM_080680.3; = p.E589K on NM_080679.2) | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); catalogued as COSV59493717; called by muse, mutect2, varscan2
- COL4A5 | c.3793C>T p.L1265= | Splice Region (SNP) | VAF 40/58 reads (69%) | catalogued as COSV100086093; called by muse, mutect2, varscan2
- COL6A2 | c.2293G>A p.E765K | Missense Mutation (SNP) | VAF 144/401 reads (36%) | SIFT tolerated (0.81); PolyPhen benign (0.007); catalogued as rs369344885; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CPVL | c.901G>T p.D301Y | Missense Mutation (SNP) | VAF 25/104 reads (24%) | SIFT tolerated (0.27); PolyPhen benign (0.005); catalogued as COSV99605141; called by muse, mutect2, varscan2
- CSMD2 | c.7499G>A p.R2500H | Missense Mutation (SNP) | VAF 43/106 reads (41%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.982); catalogued as rs775395186, COSV53948163; called by muse, mutect2, varscan2
- DAAM2 | c.2635A>G p.K879E | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0.12); catalogued as rs1360251219, COSV99224191; called by muse, mutect2, varscan2
- DNMBP | c.23G>A p.R8Q | Missense Mutation (SNP) | VAF 41/116 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs933188045, COSV60622924; called by muse, mutect2, varscan2
- DSEL | c.1981G>T p.A661S | Missense Mutation (SNP) | VAF 31/76 reads (41%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.997); catalogued as COSV100025084; called by muse, mutect2, varscan2
- EEF1A1 | c.1295C>T p.T432I | Missense Mutation (SNP) | VAF 20/53 reads (38%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.833); catalogued as COSV58549515; called by muse, mutect2, varscan2
- EEF1A1 | c.1294A>T p.T432S | Missense Mutation (SNP) | VAF 20/53 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.042); catalogued as COSV58548569, COSV58549078; called by muse, mutect2, varscan2
- ELAC2 | c.496C>T p.R166W | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs766783415, COSV100568303; called by muse, mutect2, varscan2
- ELAVL1 | c.230C>T p.A77V | Missense Mutation (SNP) | VAF 25/79 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.499); catalogued as COSV60966762; called by muse, mutect2, varscan2
- EP300 | c.3671+1G>A p.X1224_splice | Splice Site (SNP) | VAF 35/44 reads (80%) | catalogued as COSV54327591, COSV99607896; called by muse, mutect2, varscan2
- ERAP1 | c.1563G>A p.M521I | Missense Mutation (SNP) | VAF 35/51 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99700520; called by muse, mutect2, varscan2
- ERCC6L | c.1006A>G p.K336E | Missense Mutation (SNP) | VAF 84/116 reads (72%) | SIFT tolerated (0.06); PolyPhen benign (0.42); catalogued as COSV100558951; called by muse, mutect2, varscan2
- FAM83C | c.1079C>T p.S360F | Missense Mutation (SNP) | VAF 19/45 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.769); catalogued as rs951918774, COSV65582912; called by muse, mutect2, varscan2
- H3C12 | c.340C>G p.H114D | Missense Mutation (SNP) | VAF 32/97 reads (33%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.534); catalogued as COSV100377412; called by muse, mutect2, varscan2
- HAUS6 | c.623G>C p.C208S | Missense Mutation (SNP) | VAF 19/90 reads (21%) | SIFT tolerated (0.33); PolyPhen benign (0.288); catalogued as COSV100787197; called by muse, mutect2, varscan2
- HDAC11 | c.1000G>A p.A334T | Missense Mutation (SNP) | VAF 20/70 reads (29%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.003); catalogued as rs778634667, COSV55472341; called by muse, mutect2, varscan2
- HLA-B | c.742C>T p.Q248* | Nonsense Mutation (SNP) | VAF 56/178 reads (31%) | catalogued as COSV101317792, COSV69522412; called by muse, varscan2
- HUWE1 | c.12529G>A p.E4177K | Missense Mutation (SNP) | VAF 16/23 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV53351298; called by muse, mutect2, varscan2
- ITGB2 | c.763G>A p.V255I | Missense Mutation (SNP) | VAF 19/81 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.365); catalogued as rs200206541, COSV99043477; called by muse, mutect2, varscan2
- JUP | c.1255A>C p.T419P | Missense Mutation (SNP) | VAF 35/81 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100159253; called by muse, mutect2, varscan2
- KRT33B | c.610C>T p.Q204* | Nonsense Mutation (SNP) | VAF 22/56 reads (39%) | catalogued as COSV99290417; called by muse, mutect2, varscan2
- MEF2B | c.20A>G p.Q7R | Missense Mutation (SNP) | VAF 19/63 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.118); catalogued as rs1006993781, COSV99364208; called by muse, mutect2, varscan2
- MFSD10 | c.413G>A p.R138Q | Missense Mutation (SNP) | VAF 33/92 reads (36%) | SIFT tolerated (0.19); PolyPhen benign (0.233); catalogued as rs780962236, COSV99295872; called by muse, mutect2, varscan2
- MTSS1 | c.1632G>C p.K544N | Missense Mutation (SNP) | VAF 60/94 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99412577; called by muse, mutect2, varscan2
- MZT1 | c.128C>T p.T43I | Missense Mutation (SNP) | VAF 35/83 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.011); catalogued as COSV100910047; called by muse, mutect2, varscan2
- NELL2 | c.23G>A p.R8K | Missense Mutation (SNP) | VAF 63/147 reads (43%) | SIFT tolerated, low confidence (0.94); PolyPhen benign (0); catalogued as COSV100418393; called by muse, mutect2, varscan2
- NHLH1 | c.274A>T p.N92Y | Missense Mutation (SNP) | VAF 24/69 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs1360314677, COSV100131321; called by muse, mutect2, varscan2
- NUDT21 | c.214G>C p.D72H | Missense Mutation (SNP) | VAF 28/76 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.073); catalogued as COSV100272851; called by muse, mutect2, varscan2
- PCDHB3 | c.1423G>A p.A475T | Missense Mutation (SNP) | VAF 187/281 reads (67%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs1554272460, COSV50598514; called by muse, mutect2, varscan2
- PLXNA2 | c.2482G>A p.G828S | Missense Mutation (SNP) | VAF 15/31 reads (48%) | SIFT tolerated (1); PolyPhen benign (0.05); catalogued as rs775525988, COSV65438628; called by muse, mutect2, varscan2
- POLK | c.1658A>G p.D553G | Missense Mutation (SNP) | VAF 23/56 reads (41%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as rs759880142, COSV99605436; called by muse, mutect2, varscan2
- PTPRU | c.4156C>T p.R1386C | Missense Mutation (SNP) | VAF 28/101 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100111220; called by muse, mutect2, varscan2
- PXDNL | c.393C>G p.F131L | Missense Mutation (SNP) | VAF 72/302 reads (24%) | SIFT tolerated (0.05); PolyPhen benign (0.348); catalogued as COSV100680321; called by muse, mutect2, varscan2
- RIPK4 | c.1846A>T p.K616* (on ENST00000352483; = p.K568* on NM_020639.3) | Nonsense Mutation (SNP) | VAF 31/81 reads (38%) | catalogued as COSV100204495; called by muse, mutect2, varscan2
- RRAS | c.624G>C p.K208N | Missense Mutation (SNP) | VAF 50/115 reads (43%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.986); catalogued as COSV99881902; called by muse, mutect2, varscan2
- SF1 | c.1791T>G p.Y597* | Nonsense Mutation (SNP) | VAF 5/14 reads (36%) | catalogued as COSV99917843; called by muse, mutect2, varscan2
- SLC7A13 | c.233G>T p.G78V | Missense Mutation (SNP) | VAF 22/107 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.707); catalogued as COSV99878321; called by muse, mutect2, varscan2
- SLC9B1 | c.810G>C p.L270F | Missense Mutation (SNP) | VAF 45/119 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.548); catalogued as rs1341254424, COSV99598969; called by muse, mutect2, varscan2
- SMARCD3 | c.901G>T p.D301Y (on ENST00000262188 / NM_001003801.2; = p.D288Y on NM_003078.4) | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV99222657; called by muse, varscan2
- SPATA6L | c.1126A>T p.R376* (on ENST00000461761 / NM_001353484.2; = p.R318* on NM_001039395.4 and 4 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 29/98 reads (30%) | catalogued as COSV101121902; called by muse, mutect2, varscan2
- TCEA1 | c.535G>C p.E179Q | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.953); catalogued as COSV101124230; called by muse, mutect2
- TGFBI | c.1624C>T p.P542S | Missense Mutation (SNP) | VAF 44/67 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100526145; called by muse, mutect2, varscan2
- THPO | c.1193G>A p.R398H (on ENST00000649095 / NM_001290003.1; = p.R258H on NM_000460.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 64/175 reads (37%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs147206404; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TMEM169 | c.428C>T p.T143M | Missense Mutation (SNP) | VAF 25/73 reads (34%) | SIFT tolerated (0.11); PolyPhen benign (0.006); catalogued as rs201548005, COSV99824300; called by muse, mutect2, varscan2
- TNFRSF10A | c.369G>A p.W123* | Nonsense Mutation (SNP) | VAF 28/110 reads (25%) | catalogued as rs1308902523, COSV99645958; called by muse, mutect2, varscan2
- TONSL | c.2432C>T p.P811L | Missense Mutation (SNP) | VAF 22/32 reads (69%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as rs756475917, COSV101340109; called by muse, varscan2
- USP46 | c.934G>C p.G312R | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV101484178; called by muse, mutect2, varscan2
- YEATS2 | c.2363A>G p.N788S | Missense Mutation (SNP) | VAF 31/71 reads (44%) | SIFT tolerated, low confidence (0.57); PolyPhen benign (0); catalogued as rs980959019, COSV100527334; called by muse, mutect2, varscan2
- ZNF385A | c.415C>T p.R139C (on ENST00000338010 / NM_001130967.3; = p.R119C on NM_015481.3) | Missense Mutation (SNP) | VAF 27/87 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.237); catalogued as rs1004929697, COSV100566721; called by muse, mutect2, varscan2
- EMILIN3 | c.2053A>G p.T685A | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT tolerated (0.51); PolyPhen benign (0); called by muse, mutect2
- GRM2 | c.1583_1584del p.Y528* | Frame Shift Del (DEL) | VAF 18/71 reads (25%) | called by mutect2, pindel, varscan2
- HERC2P3 | n.185G>T | Splice Region (SNP) | VAF 4/32 reads (13%) | called by mutect2, varscan2
- HLA-DRB1 | c.330_331dup p.N111Tfs*19 | Frame Shift Ins (INS) | VAF 12/40 reads (30%) | called by mutect2, varscan2
- NLRC5 | c.4070del p.T1357Sfs*2 | Frame Shift Del (DEL) | VAF 26/75 reads (35%) | called by mutect2, pindel, varscan2
- NLRC5 | c.4919+3_4919+6del p.X1640_splice | Splice Site (DEL) | VAF 14/35 reads (40%) | called by pindel, varscan2
- ADD2 | c.39G>A p.P13= | Silent (SNP) | VAF 41/108 reads (38%) | catalogued as rs782510605, COSV100034359; called by muse, mutect2, varscan2
- DEFB135 | c.156A>G p.E52= | Silent (SNP) | VAF 28/81 reads (35%) | catalogued as COSV101198530; called by muse, mutect2, varscan2
- EPPK1 | c.2760C>T p.D920= | Silent (SNP) | VAF 59/90 reads (66%) | catalogued as rs558832291, COSV101599707; called by muse, mutect2, varscan2
- HCK | c.159G>A p.P53= | Silent (SNP) | VAF 22/57 reads (39%) | catalogued as rs202049705, COSV52947456; called by muse, mutect2, varscan2
- NQO1 | c.501C>T p.V167= | Silent (SNP) | VAF 104/300 reads (35%) | catalogued as COSV100276526; called by muse, varscan2
- PTPRT | c.855G>A p.V285= | Silent (SNP) | VAF 12/39 reads (31%) | catalogued as rs768558328, COSV100624189; called by muse, mutect2, varscan2
- RCN2 | c.912C>A p.G304= | Silent (SNP) | VAF 46/151 reads (30%) | catalogued as COSV100312665, COSV58031240; called by muse, mutect2, varscan2
- RPN2 | c.456C>T p.L152= | Silent (SNP) | VAF 27/76 reads (36%) | catalogued as COSV99411299; called by muse, mutect2, varscan2
- SLX4 | c.4458G>A p.R1486= | Silent (SNP) | VAF 128/355 reads (36%) | catalogued as COSV99567456; called by muse, varscan2
- SPATA6 | c.1466G>A p.*489= | Silent (SNP) | VAF 62/156 reads (40%) | catalogued as COSV100893639; called by muse, mutect2, varscan2
- TET2 | c.1509G>A p.E503= | Silent (SNP) | VAF 22/82 reads (27%) | catalogued as COSV99480091; called by muse, mutect2, varscan2
- TRHDE | c.544C>T p.L182= | Silent (SNP) | VAF 37/89 reads (42%) | catalogued as rs1359488677, COSV99668443; called by muse, mutect2, varscan2
- TRIM15 | c.360C>T p.D120= | Silent (SNP) | VAF 30/66 reads (45%) | catalogued as COSV100938763; called by muse, mutect2, varscan2
- ZNF224 | c.852G>A p.G284= | Silent (SNP) | VAF 74/222 reads (33%) | catalogued as COSV100425281; called by muse, mutect2, varscan2
- ZNF324B | c.1089C>T p.H363= | Silent (SNP) | VAF 14/43 reads (33%) | catalogued as COSV100351475; called by muse, mutect2, varscan2
- MOV10L1 | c.97+309C>T | Intron (SNP) | VAF 14/30 reads (47%) | catalogued as rs772445427, COSV53167964; called by muse, varscan2
- SLC22A20P | n.956G>A | RNA (SNP) | VAF 25/74 reads (34%) | catalogued as rs759312254; called by muse, mutect2, varscan2
